Somatic mutation profile of tumor specimen HCM-BROD-0047-C71-86A (aliquot HCM-BROD-0047-C71-86A-01D-A78L-36) from HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5c4bc28-96d2-4d77-b811-eff53521616b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0047-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0047-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74561964-aba0-470d-ac19-e1e549036ac7

The open-access MAF lists 273 somatic variants for this specimen: 179 protein-altering or splice-affecting, 67 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 67, Frame Shift Del 11, Nonsense Mutation 10, 3'UTR 10, Intron 9, Splice Site 4, RNA 4, Splice Region 3, In Frame Del 2, 5'Flank 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 76/132 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SH3TC2 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 25/663 reads (4%) | catalogued as rs864622663; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 204/204 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.12469A>C p.M4157L | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs774085026, COSV71289926; called by muse, mutect2
- AMBP | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 19/195 reads (10%) | catalogued as COSV54322523; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6539C>T p.S2180F | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV51848935; called by muse, mutect2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 236/238 reads (99%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, mutect2, varscan2
- ATP13A3 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV55466520; called by muse, mutect2
- BTBD7 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374714816; called by muse, mutect2, varscan2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- CD300A | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV100177900; called by muse, mutect2, varscan2
- CERKL | c.1393C>T p.R465W (on ENST00000339098 / NM_001030311.2; = p.R439W on NM_201548.5) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139300604, COSV100184198, COSV59204341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.9871C>T p.R3291W | Missense Mutation (SNP) | VAF 162/335 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772203216, COSV54535961; called by muse, mutect2, varscan2
- DNTT | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs752871188; called by muse, mutect2
- DUOX2 | c.2837G>A p.G946D | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as rs1238716178; called by muse, mutect2
- DUS3L | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 23/586 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV57831256; called by muse, mutect2
- ENPEP | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.366); catalogued as COSV54450203; called by muse, mutect2
- FAM47B | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757343285; called by muse, mutect2, varscan2
- FAM81B | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as rs767046810; called by mutect2, varscan2
- GEMIN4 | c.1381G>C p.V461L | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56748269; called by muse, mutect2
- HDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367618872, COSV51070116; called by muse, mutect2, varscan2
- HSPA12A | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as rs781974587, COSV65022946; called by muse, varscan2
- IL13RA2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs782749009, COSV54567739; called by muse, mutect2
- KEL | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 504/1204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147851584, CM165859, COSV62335323; called by muse, mutect2, varscan2
- KIR3DL2 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99552388; called by muse, mutect2
- LIPC | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 221/374 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.438); catalogued as rs756311428; called by muse, mutect2, varscan2
- LRRC4B | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65350301; called by muse, mutect2, varscan2
- LTBP1 | c.3169G>T p.E1057* (on ENST00000404816 / NM_206943.4; = p.E731* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 50/177 reads (28%) | catalogued as COSV55383251; called by muse, mutect2, varscan2
- MBNL1 | c.1091C>A p.A364E (on ENST00000282486 / NM_207293.2; = p.A358E on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs767649985; called by muse, mutect2, varscan2
- MKRN1 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 35/526 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.272); catalogued as rs1455208261; called by muse, mutect2
- MMP8 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV52631298; called by muse, mutect2
- MRGPRX4 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1444628507, COSV58589735; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- NALCN | c.3712A>G p.T1238A | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as rs1383609221; called by muse, mutect2, varscan2
- NKX2-1 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 24/856 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as CM093095; called by muse, mutect2
- OBSCN | c.10432C>A p.P3478T | Missense Mutation (SNP) | VAF 96/384 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV52753344, COSV52757886; called by muse, mutect2, varscan2
- OR2T4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 177/269 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs141022739; called by muse, mutect2, varscan2
- OR5D16 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1348504441, COSV65721182; called by muse, mutect2
- OR8H1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100477228; called by muse, mutect2
- PCLO | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 66/443 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs746437072, COSV61626152; called by muse, mutect2, varscan2
- PCSK2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs762323320, COSV52731184; called by muse, mutect2
- PEX6 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 157/311 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs575358435; called by muse, mutect2, varscan2
- PLCB2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938166611; called by muse, mutect2, varscan2
- PLOD1 | c.1055del p.P352Lfs*36 | Frame Shift Del (DEL) | VAF 50/250 reads (20%) | catalogued as COSV99538920; called by mutect2, pindel, varscan2
- POM121L12 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.161); catalogued as COSV68693041; called by muse, mutect2
- PPP1R16B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs376987738; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 109/135 reads (81%) | catalogued as rs146650273; called by pindel, varscan2
- SEC31B | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs756259622; called by muse, mutect2, varscan2
- SHANK1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53253397, COSV53258492; called by muse, mutect2, varscan2
- SLC26A1 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs565674546; called by muse, mutect2, varscan2
- SPATA22 | c.900+1G>A p.X300_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as rs1156746289; called by muse, mutect2, varscan2
- SPRR1B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs781282352, COSV100198426; called by muse, mutect2, varscan2
- TAF1L | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54265915; called by muse, mutect2, varscan2
- TNFSF9 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 178/346 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs753168707; called by muse, varscan2
- TRAV21 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs762806352; called by muse, mutect2, varscan2
- TRPM5 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 172/173 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs376847854; called by muse, mutect2, varscan2
- TSPAN6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV65957487; called by muse, mutect2, varscan2
- TTC34 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 68/69 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs769408367; called by muse, mutect2, varscan2
- TTYH1 | c.126+2T>C p.X42_splice | Splice Site (SNP) | VAF 23/82 reads (28%) | catalogued as rs1340739545; called by muse, mutect2, varscan2
- WAC | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs991762624; called by muse, mutect2, varscan2
- XRN1 | c.1346+5G>A | Splice Region (SNP) | VAF 25/103 reads (24%) | catalogued as rs749503524; called by muse, mutect2, varscan2
- ZNF160 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.198); catalogued as rs1163268625; called by muse, mutect2
- ZNF423 | c.3721G>A p.V1241M (on ENST00000563137 / NM_001379286.1; = p.V1233M on NM_015069.4) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV52206589; called by muse, mutect2, varscan2
- ZSCAN5C | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.428); catalogued as rs762862197; called by muse, mutect2, varscan2
- ABCG5 | c.249C>A p.C83* | Nonsense Mutation (SNP) | VAF 19/527 reads (4%) | called by muse, mutect2
- ACOX1 | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS20 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- APOA1 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATG2A | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C12orf50 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1QL3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); called by muse, mutect2
- CAB39 | c.288del p.D97Tfs*35 | Frame Shift Del (DEL) | VAF 32/53 reads (60%) | called by mutect2, pindel, varscan2
- CACNG3 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CAP1 | c.635del p.P212Lfs*6 | Frame Shift Del (DEL) | VAF 55/218 reads (25%) | called by mutect2, pindel, varscan2
- CBL | c.2305_2309del p.N769Gfs*2 | Frame Shift Del (DEL) | VAF 66/250 reads (26%) | called by mutect2, pindel, varscan2
- CCER2 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCL17 | c.211del p.A71Pfs*11 | Frame Shift Del (DEL) | VAF 40/309 reads (13%) | called by mutect2, pindel, varscan2
- CNTN4 | c.185G>T p.W62L | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL22A1 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CR1 | c.1749del p.H585Tfs*57 (on ENST00000367051; = p.H1035Tfs*57 on NM_000651.6) | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- CRACDL | c.28A>T p.K10* | Nonsense Mutation (SNP) | VAF 46/253 reads (18%) | called by muse, mutect2, varscan2
- CUX1 | c.1177C>T p.Q393* (on ENST00000292535 / NM_181552.4; = p.Q404* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 75/371 reads (20%) | called by muse, mutect2, varscan2
- CWC22 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CWH43 | c.1267-1_1268del p.X423_splice | Splice Site (DEL) | VAF 28/71 reads (39%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF15 | c.230+2T>C p.X77_splice | Splice Site (SNP) | VAF 68/312 reads (22%) | called by muse, mutect2, varscan2
- DGLUCY | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- DLK1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DUS3L | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); called by muse, mutect2
- EDEM3 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- EIF2AK4 | c.2468T>C p.V823A | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EIF2B3 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ENPP4 | c.9A>T p.L3F | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERI2 | c.66T>A p.N22K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- FAM98B | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FKBP5 | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FPR1 | c.526_528del p.C176del | In Frame Del (DEL) | VAF 93/155 reads (60%) | called by mutect2, pindel, varscan2
- FRMD4A | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2
- FST | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- GALNT1 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.133); called by muse, mutect2
- GATA2 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- GNAS | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, varscan2
- GOLGA8J | c.72del p.N24Kfs*49 | Frame Shift Del (DEL) | VAF 40/42 reads (95%) | called by mutect2, varscan2
- GPR137C | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 13/425 reads (3%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.796); called by muse, mutect2
- HERC5 | c.1910A>G p.N637S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- HIF3A | c.682C>G p.H228D (on ENST00000377670 / NM_152795.4; = p.H159D on NM_022462.4) | Missense Mutation (SNP) | VAF 101/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HOXD11 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HSF4 | c.730-4A>T | Splice Region (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- HSH2D | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- IFI6 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- INIP | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- INTS4 | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KDELR2 | c.180C>G p.N60K | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KDM3A | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- KLK2 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- LAMA1 | c.7965-4del | Splice Region (DEL) | VAF 46/162 reads (28%) | called by mutect2, pindel, varscan2
- LAMA2 | c.1033A>G p.N345D | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LIMK2 | c.1381T>G p.L461V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MAP2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MRGPRF | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MSH5 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- MUC16 | c.6512C>A p.T2171K | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.1060A>T p.R354W | Missense Mutation (SNP) | VAF 121/156 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MUC22 | c.4326_4331del p.S1443_E1444del | In Frame Del (DEL) | VAF 72/501 reads (14%) | called by mutect2, varscan2
- MYH9 | c.4828G>T p.A1610S | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.066); called by muse, mutect2
- MYO1B | c.1673A>T p.N558I | Missense Mutation (SNP) | VAF 187/261 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- NFASC | c.3039A>G p.I1013M | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- NLRP2 | c.2975del p.N992Ifs*8 | Frame Shift Del (DEL) | VAF 86/420 reads (20%) | called by mutect2, pindel, varscan2
- NME8 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- NR1I2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- OR11A1 | c.655T>A p.Y219N | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2A2 | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 341/732 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- OR2L3 | c.645T>A p.C215* | Nonsense Mutation (SNP) | VAF 149/226 reads (66%) | called by muse, mutect2, varscan2
- OR4K5 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OS9 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PADI1 | c.990_995dup p.K331_A332dup | In Frame Ins (INS) | VAF 38/65 reads (58%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.812A>T p.E271V (on ENST00000374531 / NM_001037293.2; = p.E303V on NM_053016.6) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA | c.4531A>G p.S1511G | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PCDHA2 | c.1618G>C p.A540P | Missense Mutation (SNP) | VAF 681/688 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PFKL | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PITRM1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- PKHD1 | c.11335C>A p.P3779T | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNISR | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PPL | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCB | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 25/764 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- PRLHR | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRODH2 | c.695T>C p.L232P (on ENST00000301175; = p.L156P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RFXANK | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 203/801 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS10 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPL15 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 34/200 reads (17%) | called by muse, mutect2, varscan2
- RREB1 | c.3340A>C p.T1114P | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RSF1 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RYR1 | c.2246T>A p.L749H | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCYL1 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SIPA1L2 | c.2981T>C p.I994T | Missense Mutation (SNP) | VAF 21/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIPA1L3 | c.4021A>G p.M1341V | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A51 | c.432G>C p.L144F | Missense Mutation (SNP) | VAF 169/324 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC4A2 | c.3608T>C p.V1203A | Missense Mutation (SNP) | VAF 145/429 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A17 | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.023); called by muse, mutect2
- SLU7 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 92/106 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPG7 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); called by muse, mutect2
- SRBD1 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNPO | c.1928T>C p.V643A (on ENST00000394243 / NM_001166208.2; = p.V399A on NM_007286.6) | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TAF2 | c.2930C>T p.T977I | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD7 | c.2309A>T p.K770M | Missense Mutation (SNP) | VAF 87/628 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TEX13C | c.2789A>T p.Q930L | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TGOLN2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TMEM186 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TNNI2 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL5 | c.3449T>G p.F1150C | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- VAMP3 | c.58A>T p.N20Y | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- WWP1 | c.2177T>C p.V726A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZHX3 | c.322del p.T108Pfs*57 | Frame Shift Del (DEL) | VAF 19/179 reads (11%) | called by mutect2, pindel, varscan2
- ZNF285 | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 80/143 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF439 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF461 | c.1586A>T p.K529M | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ZNF721 | c.2604_2605del p.Y869Cfs*3 (on ENST00000338977; = p.Y881Cfs*3 on NM_133474.4) | Frame Shift Del (DEL) | VAF 100/289 reads (35%) | called by mutect2, pindel, varscan2
- ZNF732 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF747 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- AHNAK2 | c.5151C>A p.V1717= | Silent (SNP) | VAF 144/817 reads (18%) | called by muse, mutect2, varscan2
- APOBR | c.2205G>A p.A735= (on ENST00000431282; = p.A744= on NM_018690.4) | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs369577053; called by muse, mutect2, varscan2
- ARHGAP36 | c.1371G>A p.R457= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV52265029; called by muse, mutect2
- BEGAIN | c.1431C>T p.S477= | Silent (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1860C>T p.D620= | Silent (SNP) | VAF 117/117 reads (100%) | catalogued as rs569086347, COSV57895134; called by muse, mutect2, varscan2
- CAMTA2 | c.36C>T p.N12= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- CATSPERG | c.2271C>T p.R757= | Silent (SNP) | VAF 229/709 reads (32%) | called by muse, mutect2, varscan2
- CEP83 | c.954A>T p.S318= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- COL1A1 | c.3183C>A p.G1061= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- CSMD3 | c.3210T>C p.D1070= (on ENST00000297405 / NM_001363185.1; = p.D966= on NM_052900.3) | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- CUX1 | c.1176G>T p.L392= (on ENST00000292535 / NM_181552.4; = p.L403= on NM_001913.5) | Silent (SNP) | VAF 73/372 reads (20%) | called by muse, mutect2, varscan2
- CUX1 | c.1713A>G p.Q571= | Silent (SNP) | VAF 24/711 reads (3%) | called by muse, mutect2
- CXCR1 | c.696C>G p.A232= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- CYBB | c.150G>C p.L50= | Silent (SNP) | VAF 97/292 reads (33%) | called by muse, mutect2, varscan2
- DIDO1 | c.4143C>T p.D1381= | Silent (SNP) | VAF 182/408 reads (45%) | called by muse, mutect2, varscan2
- DISP2 | c.1086C>T p.A362= | Silent (SNP) | VAF 19/483 reads (4%) | called by muse, mutect2
- DUSP26 | c.528G>T p.V176= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV56361050; called by muse, mutect2, varscan2
- DYSF | c.2718C>T p.D906= | Silent (SNP) | VAF 75/274 reads (27%) | catalogued as rs772806555, COSV50266247; called by muse, mutect2, varscan2
- ELAVL2 | c.363T>C p.S121= | Silent (SNP) | VAF 34/266 reads (13%) | called by muse, mutect2, varscan2
- EPC1 | c.435C>T p.R145= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- FAM189B | c.1755G>A p.R585= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- FAM216B | c.300T>C p.A100= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- FBXO7 | c.99C>T p.S33= | Silent (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- FLG | c.1563G>T p.G521= | Silent (SNP) | VAF 289/502 reads (58%) | catalogued as rs763639841; called by muse, mutect2, varscan2
- FOXD2 | c.1014G>C p.A338= | Silent (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- FOXD4L4 | c.1017G>A p.Q339= | Silent (SNP) | VAF 133/835 reads (16%) | called by muse, mutect2, varscan2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 138/284 reads (49%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GCNT2 | c.321C>T p.F107= | Silent (SNP) | VAF 35/360 reads (10%) | catalogued as rs113929825; called by muse, mutect2
- GIMAP8 | c.1638G>A p.A546= | Silent (SNP) | VAF 77/250 reads (31%) | catalogued as rs897850406, COSV56231089; called by muse, mutect2, varscan2
- GIPC1 | c.219C>A p.I73= | Silent (SNP) | VAF 86/707 reads (12%) | called by muse, mutect2, varscan2
- GUCY2D | c.1311G>A p.P437= | Silent (SNP) | VAF 165/165 reads (100%) | catalogued as rs775635196, COSV54696534; called by muse, mutect2, varscan2
- GYPA | c.246A>G p.Q82= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV51638496; called by muse, mutect2
- HAS1 | c.219C>T p.F73= | Silent (SNP) | VAF 166/210 reads (79%) | called by muse, mutect2, varscan2
- HMCN2 | c.5154G>A p.Q1718= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- HMCN2 | c.12579G>A p.A4193= | Silent (SNP) | VAF 61/104 reads (59%) | catalogued as rs942933262, COSV52983544; called by muse, mutect2, varscan2
- IQGAP2 | c.2967A>G p.V989= | Silent (SNP) | VAF 153/658 reads (23%) | called by muse, mutect2, varscan2
- KDR | c.1119C>T p.S373= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- LY86 | c.291C>T p.F97= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as rs1308965562, COSV100041002, COSV57913518; called by muse, mutect2
- MBNL1 | c.1092A>C p.A364= (on ENST00000282486 / NM_207293.2; = p.A358= on NM_021038.5 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as rs756129529; called by muse, mutect2, varscan2
- MMP14 | c.1038T>C p.N346= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- MRGPRF | c.921G>A p.R307= | Silent (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- NEIL3 | c.1599T>C p.C533= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1201712501; called by muse, mutect2, varscan2
- NLRP2 | c.1764C>T p.C588= | Silent (SNP) | VAF 298/394 reads (76%) | catalogued as rs781443340, COSV54759813; called by muse, mutect2, varscan2
- OR5M10 | c.768C>T p.F256= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV73242322; called by muse, mutect2, varscan2
- PCDHB4 | c.2109G>A p.S703= | Silent (SNP) | VAF 20/540 reads (4%) | catalogued as rs149213680, COSV52023270; called by muse, mutect2
- PCNX2 | c.2958G>A p.L986= | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- PDE6C | c.21T>C p.V7= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- PERM1 | c.1860C>T p.F620= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as rs904502571; called by muse, mutect2
- PPL | c.1194G>A p.P398= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs752842442, COSV100630759; called by muse, mutect2, varscan2
- PRRC2B | c.3693T>C p.S1231= | Silent (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- RYR1 | c.5400T>C p.P1800= | Silent (SNP) | VAF 43/216 reads (20%) | called by muse, mutect2, varscan2
- SART1 | c.111A>G p.K37= | Silent (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- SCN5A | c.873C>T p.N291= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as rs376515775; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELE | c.315G>A p.R105= | Silent (SNP) | VAF 112/251 reads (45%) | catalogued as rs759912786, COSV60974350; called by muse, mutect2, varscan2
- SEMG2 | c.285A>G p.K95= | Silent (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- SEZ6 | c.402G>A p.Q134= | Silent (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- TBR1 | c.1533C>A p.A511= | Silent (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- THSD7B | c.786C>T p.S262= | Silent (SNP) | VAF 121/260 reads (47%) | catalogued as rs576768669, COSV55675824, COSV55679461; called by muse, mutect2, varscan2
- TMEM132D | c.42G>A p.S14= | Silent (SNP) | VAF 40/349 reads (11%) | catalogued as rs1464488554, COSV70613792; called by muse, mutect2, varscan2
- TREML1 | c.720T>C p.F240= | Silent (SNP) | VAF 60/332 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.48555T>A p.G16185= (on ENST00000591111; = p.G8761= on NM_003319.4) | Silent (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- VANGL1 | c.1320C>T p.F440= | Silent (SNP) | VAF 12/392 reads (3%) | called by muse, mutect2
- VAX2 | c.606G>A p.A202= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as rs782471705, COSV52265915; called by muse, mutect2, varscan2
- WWC1 | c.1467C>T p.A489= | Silent (SNP) | VAF 197/197 reads (100%) | called by muse, mutect2, varscan2
- ZNF18 | c.303G>A p.V101= | Silent (SNP) | VAF 197/197 reads (100%) | catalogued as rs1217188275, COSV59550512; called by muse, mutect2, varscan2
- ZNF335 | c.462T>C p.S154= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- ZNF404 | c.1071T>C p.C357= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV60986809; called by muse, mutect2, varscan2
- ABTB1 | c.-59C>T | 5'UTR (SNP) | VAF 12/228 reads (5%) | catalogued as rs1282477667; called by muse, mutect2
- AC005008.1 | chr7:81187834 A>G | 5'Flank (SNP) | VAF 40/316 reads (13%) | called by muse, mutect2, varscan2
- AHRR | c.245-8802G>A | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- ARFRP1 | c.418-490C>G | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, varscan2
- CCDC7 | chr10:32876457 T>C | 3'Flank (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- COPB2 | c.141+157A>G | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- DCHS2 | n.4055T>C | RNA (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- EAF2 | c.*22A>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- GIP | c.*13C>T | 3'UTR (SNP) | VAF 11/175 reads (6%) | catalogued as rs1427879404; called by muse, mutect2
- GIPR | c.1152+47C>T | Intron (SNP) | VAF 16/374 reads (4%) | called by muse, mutect2
- GIT2 | c.1393-1363C>G | Intron (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- GPRC5B | c.*3089T>C | 3'UTR (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- GUCY2EP | n.1194G>A | RNA (SNP) | VAF 42/48 reads (88%) | called by muse, mutect2, varscan2
- HCN1 | c.*4C>T | 3'UTR (SNP) | VAF 206/420 reads (49%) | called by muse, mutect2, varscan2
- LRRC39 | c.953-272G>A | Intron (SNP) | VAF 58/204 reads (28%) | called by muse, varscan2
- MIR7-3 | n.74A>T | RNA (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- MRPS18A | c.377-20C>T | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- NRBP2 | c.*183G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PTPN18 | c.376-9C>T | Intron (SNP) | VAF 44/220 reads (20%) | called by muse, mutect2, varscan2
- QRICH2 | c.*45C>T | 3'UTR (SNP) | VAF 119/120 reads (99%) | catalogued as rs770433642, COSV53156824; called by muse, mutect2, varscan2
- RNF32 | chr7:156640185 G>A | 5'Flank (SNP) | VAF 60/527 reads (11%) | catalogued as rs1197883958; called by muse, mutect2, varscan2
- RPL31 | c.*2C>A | 3'UTR (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- SCN4B | c.*2757G>A | 3'UTR (SNP) | VAF 149/178 reads (84%) | catalogued as rs1232026663; called by muse, mutect2, varscan2
- SIGLEC14 | c.*8C>T | 3'UTR (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- SLC29A3 | c.*344G>A | 3'UTR (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- UGT2B27P | n.1019C>T | RNA (SNP) | VAF 18/194 reads (9%) | catalogued as rs1304847336; called by muse, mutect2
- VIM | c.564-48C>T | Intron (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
